Somatic mutation profile of tumor specimen TCGA-KK-A8I4-01A (aliquot TCGA-KK-A8I4-01A-11D-A364-08) from TCGA case TCGA-KK-A8I4, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.9 years (23,706 days).
Specimen TCGA-KK-A8I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e89d405-ff4f-4835-a571-7a77cc17ab6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8I4-11A (Solid Tissue Normal), aliquot TCGA-KK-A8I4-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca714d19-f1b9-456b-b1ad-d9e97feeb87a

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR1A | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100146940; called by muse, mutect2, varscan2
- AXL | c.1795A>G p.R599G (on ENST00000301178 / NM_021913.5; = p.R590G on NM_001699.6) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs1352620056, COSV99997475; called by muse, mutect2, varscan2
- BMP4 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99817210; called by muse, mutect2, varscan2
- CAPN5 | c.473C>T p.A158V (on ENST00000456580; = p.A118V on NM_004055.5) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs782178755, COSV99582693; called by muse, mutect2
- COL4A2 | c.99G>C p.A33= | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100847586, COSV64630687; called by muse, mutect2
- EDN3 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs142051051, COSV61107321; called by muse, mutect2, varscan2
- HMGCS1 | c.745A>T p.N249Y | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100285124; called by muse, mutect2
- HSD3B2 | c.460T>C p.Y154H | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749638934, COSV101027591; called by muse, mutect2, varscan2
- KLK12 | c.516C>A p.C172* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as COSV51575964, COSV99142131; called by muse, mutect2
- KRT27 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs116334559, COSV100053247; called by muse, mutect2, varscan2
- NXPE4 | c.1027G>A p.G343R (on ENST00000375478 / NM_001077639.2; = p.G59R on NM_017678.3) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.766); catalogued as COSV100970610; called by muse, mutect2, varscan2
- PRDM10 | c.3197C>T p.T1066M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs773270883, COSV58798992; called by muse, mutect2, varscan2
- RASSF9 | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV100771661; called by muse, mutect2, varscan2
- SIPA1 | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1399324582, COSV101255985; called by muse, mutect2
- SLC12A5 | c.769G>A p.G257S (on ENST00000454036 / NM_001134771.2; = p.G234S on NM_020708.5) | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765343735, COSV54798288; called by muse, mutect2, varscan2
- HSPA5 | c.194_195del p.Y65Cfs*6 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- RANBP2 | c.373_374del p.F125Pfs*8 | Frame Shift Del (DEL) | VAF 22/228 reads (10%) | called by mutect2, pindel, varscan2
- ANK2 | c.5835G>A p.T1945= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs1216296600, COSV100004876; called by muse, mutect2, varscan2
- CFAP61 | c.2172T>C p.N724= | Silent (SNP) | VAF 17/202 reads (8%) | catalogued as COSV99847121; called by muse, mutect2
- MBP | c.591G>A p.P197= (on ENST00000355994 / NM_001025101.2; = p.P90= on NM_002385.3) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs371962636, COSV100592854; called by muse, mutect2
- TBC1D9B | c.2739C>T p.H913= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs780687225, COSV100783701; called by muse, varscan2
- TTL | c.621G>A p.V207= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs779959386, COSV99271734; called by muse, mutect2, varscan2
